Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6370, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6370-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE TISSUE

TCGA - G9 - 6370

SPECIMEN(S):

A. PROSTATE TISSUE

GROSS DESCRIPTION:

A. PROSTATE TISSUE

Received fresh labeled with the patient's identification and "prostate" is a 60-g resected prostate gland measuring 5.1 cm from right lateral to left lateral, 4.3 cm from anterior to posterior, and 3.2 cm from apex to base. Capsule is smooth, red, and intact. Ink code: Anterior-orange, apex-red, base.-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of apex and base, the prostate weighs 38 g; it consists of a nodular tan parenchyma. The right seminal vesicle is 4.2 x 2 x 0.7 cm and the left is 4.4 x 2.5 x 0.7 cm; they consist of cystic tan tissue. The right vas deferens is 3.6 x 0.6 cm and the left is detached and is 3.1 x 0.5 cm; they consist of tubular tan tissue. Tissue is procured (20 g).

Submitted entirely:

A1-A4: perpendicular sections of apex submitted clockwise from anterior to left lateral

A5: level 1, right anterior

A6: level 1, right posterior

A7: level 1, left anterior

A8: level 1, left posterior

A9: level 2, right lateral and posterior capsule

A10: level 2, posterior and left lateral capsule

A11: level 2, anterior capsule

A12: level 3, right lateral capsule

A13: level 3, posterior capsule

A14: level 3, left lateral and anterior capsule

A15: level 4, right anterior

A16-A17: level 4, right posterior (bisected)

A18: level 4, left anterior

A19: level 4, left posterior

A20-A21: right mid-base, perpendicular sections

A22-A23: left mid base perpendicular sections

A24-A26: right lateral base, perpendicular sections

A27-A29: left lateral base, perpendicular sections

A30: right posterior base including root of seminal vesicle and vas deferens

A31: left posterior base including root of seminal vesicle and vas deferens

A32: right seminal vesicle and vas deferens

A33: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 3+4 (7/10) IN 16 % OF PROSTATIC TISSUE EXAMINED

- RIGHT AND LEFT LOBES, APEX, BASE, ANTERIOR AND POSTERIOR ARE INVOLVED BY TUMOR

-TUMOR IS PRESENT IN RIGHT SEMINAL VESICLE (SLIDES A31 & A16)

-MICROSCOPIC INVASION TO PERIPROSTATIC ADIPOSE TISSUE (2 FOCI)

- Level1, left posterior; (Slide A8)

- Right posterior base including the root of right seminal vesicle (SlideA31)

- PERI-NEURAL INVASION IS PRESENT

- HIGH GRADE PROSTATIC INTRAEPITHELIA NEOPLASIA IS PRESENT.

- RESECTION MARGINS ARE NOT INVOLVED BY TUMOR.

- NO DEFINITIVE VASCULAR OR LYMPHATIC INVASION ARE IDENTIFIED

- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1)

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE TISSUE

Location: Left

[page 2 of 2]
[REDACTED]

Right
Posterior lateral
Apical
Basal
Anterior
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 16%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: Yes
Right
Muscular Wall Invasion: Yes
Lumen Invasion: No
Periprostatic Fat Involved: Yes
Details: Left and right posterior
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: Negative Right 0 / 1
Other Pathologic Findings: Chronic inflammation
Pathological Staging (pTNM): T 3b N 0 M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pMX: Cannot be assessed

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

[REDACTED]

Source: NCI Genomic Data Commons file ed0134c8-4dff-4c4f-88c5-43af1c742a36 (TCGA-G9-6370.FA0332E6-D535-45C0-8ED9-9B36816F1350.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).